Somatic mutation profile of tumor specimen TCGA-2G-AAKD-01A (aliquot TCGA-2G-AAKD-01A-31D-A42Y-10) from TCGA case TCGA-2G-AAKD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 18.7 years (6,814 days).
Specimen TCGA-2G-AAKD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 990de698-9ef1-4d0b-bd8b-11f2dea1f7e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKD-10A (Blood Derived Normal), aliquot TCGA-2G-AAKD-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dfd9f9a-b4d6-42ac-9de0-908f8d256901

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, RNA 1, Nonsense Mutation 1, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPCD | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382106199; called by muse, mutect2, varscan2
- FAT1 | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767041778, COSV71672328; called by muse, mutect2, varscan2
- ITGA7 | c.1054G>A p.E352K (on ENST00000555728; = p.E308K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs746101495, COSV57696921, COSV99145161; called by muse, mutect2, varscan2
- NEIL3 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV52814493; called by muse, mutect2, varscan2
- SPATA18 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs193921037, COSV54644596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAL3ST2 | c.462C>G p.Y154* | Nonsense Mutation (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- LAMA3 | c.3954_3987del p.C1319Pfs*101 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- MINDY2 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2
- MSL2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRLR | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CALB1 | c.445C>T p.L149= | Silent (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.516C>T p.D172= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- ZBBX | c.1182C>T p.V394= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs758944943; called by muse, mutect2, varscan2
- ENY2 | c.-31C>T | 5'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.318G>A | RNA (SNP) | VAF 19/72 reads (26%) | catalogued as rs1308940355; called by muse, mutect2, varscan2
- PRKAG2 | c.1234-51T>G | Intron (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
